Somatic mutation profile of tumor specimen TCGA-19-4065-02A (aliquot TCGA-19-4065-02A-11D-2280-08) from TCGA case TCGA-19-4065, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.3 years (13,257 days).
Specimen TCGA-19-4065-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd8c0cd8-e93f-4bb3-b128-c02a9c908cf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-4065-10A (Blood Derived Normal), aliquot TCGA-19-4065-10A-01D-2280-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78271628-3f5a-4b99-a1e4-ccfd1fbdc2f8

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 19, Splice Site 5, Nonsense Mutation 2, In Frame Del 2, 3'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH6 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs267606905, CM052259, COSV100676195, COSV100676755; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4330A>G p.K1444E (on ENST00000358273 / NM_001042492.3; = p.K1423E on NM_000267.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137854550, CM143401, CM145726, CM920506, COSV62204136, COSV62222725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.81T>G p.Y27* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | hotspot (GDC flag); catalogued as CM128488, COSV64291164, COSV64310374; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 59/107 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.1453G>A p.D485N (on ENST00000295851 / NM_001375719.1; = p.D447N on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99651811; called by muse, mutect2, varscan2
- AC104452.1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99864558; called by muse, mutect2, varscan2
- ADAMTS1 | c.2356T>C p.S786P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99535768; called by muse, mutect2, varscan2
- ADAMTS6 | c.462+2T>C p.X154_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV101125112; called by muse, mutect2, varscan2
- AHCY | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); catalogued as rs1391812572, COSV99463917; called by muse, mutect2, varscan2
- AHSG | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99890047; called by muse, mutect2, varscan2
- ALDH2 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV99922968; called by muse, mutect2, varscan2
- ATP8A2 | c.527T>A p.V176E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99682092; called by muse, mutect2, varscan2
- BLM | c.4102T>C p.S1368P | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs587778104, COSV100757217; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CFAP44 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99869621; called by muse, mutect2, varscan2
- CHEK1 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV99629672; called by muse, mutect2, varscan2
- CLVS2 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV99252820; called by muse, mutect2, varscan2
- COG4 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100091794; called by muse, mutect2, varscan2
- COL2A1 | c.2563G>A p.G855S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193507525, COSV100475237; called by muse, mutect2, varscan2
- COL5A1 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs772211736, COSV65678216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.3383A>G p.N1128S | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs1252229931, COSV99852356; called by muse, mutect2, varscan2
- CPM | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV100615097; called by muse, mutect2, varscan2
- CSNK1G3 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100631287; called by muse, mutect2, varscan2
- CSRP3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs145300736, CM103199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL2 | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV100233890; called by muse, mutect2, varscan2
- ELAPOR2 | c.2865-2A>G p.X955_splice (on ENST00000450689 / NM_001142749.3; = p.X788_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as rs1235705522, COSV51888117, COSV99788826; called by muse, mutect2, varscan2
- ESS2 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99350913; called by muse, mutect2, varscan2
- FAM91A1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs754338365, COSV100593440, COSV58235865; called by muse, mutect2, varscan2
- FRMD7 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213344421, COSV53748805; called by muse, mutect2, varscan2
- GALNT1 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99322192; called by muse, mutect2, varscan2
- GRID2 | c.834T>G p.I278M | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV99941112; called by muse, mutect2, varscan2
- GRK2 | c.1070T>A p.M357K | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100419669; called by muse, mutect2, varscan2
- HLF | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56832572; called by muse, mutect2, varscan2
- HMGCR | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55314800, COSV99843272; called by muse, mutect2, varscan2
- HYDIN | c.15025G>A p.A5009T | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs199657414, COSV66639103; called by muse, mutect2, varscan2
- KCNQ3 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs747670092, COSV101196153; called by muse, mutect2, varscan2
- KCTD15 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99393197; called by muse, mutect2, varscan2
- KIF2B | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99274508; called by muse, mutect2, varscan2
- KMT2E | c.3262A>G p.T1088A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99996355; called by muse, mutect2, varscan2
- LRP8 | c.1759A>C p.N587H | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100036502; called by muse, mutect2, varscan2
- LRRC32 | c.608A>C p.N203T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99476958; called by muse, mutect2, varscan2
- MMUT | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99222346; called by muse, mutect2, varscan2
- MUC20 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as rs1334943332, COSV57853045; called by muse, mutect2, varscan2
- MYO9A | c.1878C>A p.D626E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.241); catalogued as COSV61853365; called by muse, mutect2, varscan2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2, varscan2
- NETO1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172565808, COSV100198073; called by muse, mutect2, varscan2
- NFATC1 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99501699; called by muse, mutect2, varscan2
- NIBAN2 | c.1722C>G p.S574R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100031526; called by muse, mutect2, varscan2
- OR2AG1 | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100264876, COSV56626946; called by muse, mutect2, varscan2
- OR2T10 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV57897532; called by muse, mutect2, varscan2
- OR2T12 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100527785, COSV58779944; called by muse, mutect2, varscan2
- OR2W1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.116); catalogued as COSV101013910; called by muse, mutect2, varscan2
- OR2W3 | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100831575; called by muse, mutect2, varscan2
- OSBPL5 | c.2398+1G>T p.X800_splice | Splice Site (SNP) | VAF 11/108 reads (10%) | catalogued as COSV99720299; called by muse, mutect2
- PAK6 | c.865T>C p.S289P | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99544563; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.188A>T p.E63V (on ENST00000374531 / NM_001037293.2; = p.E61V on NM_007203.5) | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100092406; called by muse, mutect2, varscan2
- PEG10 | c.158A>G p.E53G (on ENST00000482108 / NM_001040152.2; = p.E87G on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV101509839; called by muse, mutect2, varscan2
- POLRMT | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs576840960, COSV101648653; called by muse, mutect2, varscan2
- PRKACA | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100432056; called by muse, mutect2, varscan2
- RALGPS2 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100860619; called by muse, mutect2, varscan2
- RPGRIP1 | c.2293T>C p.C765R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.212); catalogued as COSV99251086; called by muse, mutect2
- RXFP1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs778516371, COSV100313488; called by muse, mutect2, varscan2
- SCRN3 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs756474857, COSV99767316; called by muse, mutect2, varscan2
- SLC30A3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs759566076, COSV51984503; called by muse, mutect2, varscan2
- SPAG1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1358693993, COSV52563388, COSV99308988; called by muse, mutect2
- SPTAN1 | c.7415A>G p.N2472S | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63988239; called by muse, mutect2, varscan2
- SUN3 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99814094; called by muse, mutect2, varscan2
- TAOK3 | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV101183568; called by muse, mutect2, varscan2
- TAX1BP1 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV99604480; called by muse, mutect2, varscan2
- THSD4 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99965688; called by muse, mutect2, varscan2
- THSD7B | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs568467115, COSV55677825; called by muse, mutect2, varscan2
- TMIGD1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV100187242; called by muse, mutect2, varscan2
- TRAF3IP2 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV100389745; called by muse, mutect2, varscan2
- UBE2D2 | c.398+1G>A p.X133_splice | Splice Site (SNP) | VAF 15/84 reads (18%) | catalogued as COSV99551380; called by muse, mutect2, varscan2
- VRTN | c.1685T>A p.V562D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99832266; called by muse, mutect2, varscan2
- XCL1 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100892202, COSV63192393, COSV63192911; called by muse, mutect2, varscan2
- XCL1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as rs748586230, COSV100892203; called by muse, mutect2, varscan2
- ZHX2 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100073144; called by muse, mutect2, varscan2
- ZNF124 | c.853A>G p.I285V (on ENST00000543802 / NM_001297568.1; = p.I223V on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100517795; called by muse, mutect2, varscan2
- ALG12 | c.37del p.L13Cfs*8 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- CEP290 | c.3458_3461+13del p.X1153_splice | Splice Site (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- KRT4 | c.552_560del p.E185_L187del | In Frame Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel
- MICU2 | c.495_500del p.L166_L167del | In Frame Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- ACE | c.2457A>G p.V819= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99326110; called by muse, mutect2, varscan2
- ARID4B | c.135T>C p.D45= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99935665; called by muse, mutect2, varscan2
- BTG3 | c.654A>G p.R218= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100336299; called by muse, mutect2, varscan2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 24/190 reads (13%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- COPS5 | c.843A>G p.G281= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100769951; called by muse, mutect2, varscan2
- DNAH3 | c.4047C>T p.D1349= | Silent (SNP) | VAF 93/181 reads (51%) | catalogued as rs774286374, COSV54525528; called by muse, mutect2, varscan2
- FLT4 | c.1797C>T p.H599= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs200474566, COSV56100158; called by muse, mutect2, varscan2
- HCN1 | c.219C>T p.G73= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100301388; called by muse, varscan2
- LDLR | c.1605C>T p.D535= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as COSV99369960; called by muse, mutect2, varscan2
- LRFN2 | c.663C>G p.S221= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100599043; called by muse, mutect2, varscan2
- MAGEB6 | c.777C>T p.G259= | Silent (SNP) | VAF 55/92 reads (60%) | catalogued as rs765918379, COSV100983642; called by muse, mutect2, varscan2
- MPRIP | c.1089C>G p.P363= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs546186002, COSV100505759; called by muse, mutect2, varscan2
- OR52B6 | c.390C>T p.H130= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV100798461; called by muse, mutect2, varscan2
- PPP4R4 | c.2280G>A p.S760= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs367998986; called by muse, mutect2, varscan2
- PXDN | c.4155C>T p.F1385= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs747448989, COSV53238224, COSV99413588; called by muse, mutect2, varscan2
- RIOX2 | c.666T>C p.H222= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs1044688829, COSV100328081; called by muse, mutect2, varscan2
- SLC9A4 | c.915C>T p.I305= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV54838915; called by muse, mutect2, varscan2
- ST3GAL6 | c.234C>T p.S78= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as rs143638537; called by muse, mutect2, varscan2
- ZNF462 | c.4587C>T p.G1529= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs373087468; called by muse, mutect2, varscan2
- NELL2 | c.56-197G>T | Intron (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100419734; called by muse, mutect2
- TMEM167B | chr1:109100481 G>A | 3'Flank (SNP) | VAF 3/18 reads (17%) | catalogued as rs1243055874; called by muse, mutect2
